Gene-level copy-number profile of tumor specimen TCGA-CV-6945-01A from TCGA case TCGA-CV-6945, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 41.5 years (15,158 days).
Specimen TCGA-CV-6945-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.295a442e-b8a8-4eb2-9a5a-2656f692a289.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-6945-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/55c64e9a-74f8-45c9-8f05-16782588cc5a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 26; copy number 2: 13,924; copy number 3: 18,340; copy number 4: 19,709; copy number 5: 2,481; copy number 6: 4,040; copy number 7: 966; copy number 8: 48; copy number 9: 116; copy number 11: 50; copy number 13: 33; copy number 18: 45; copy number 20: 14; copy number 28: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-6945-01A-11D-1910-01): tumor purity 0.4, ploidy 3.43, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 284 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:174,547,141–174,776,720, 1 gene, copy number 9 (within-gene range 2–9): AC010894.2.
- chr2:174,559,572–174,682,916, 1 gene, copy number 9 (within-gene range 2–9): WIPF1.
- chr2:174,719,908–178,142,651, 86 genes, copy number 9–13 (broad region; genes not listed).
- chr5:179,732,822–181,206,120, 61 genes, copy number 9 (broad region; genes not listed).
- chr10:78,179,174–79,316,528, 11 genes, copy number 11 (within-gene range 7–11): AC012560.1, LINC00595, AC010163.3, AC010163.1, AC010163.2, SNORA71, AL583852.1, AC016820.1, ZMIZ1-AS1, AL356753.1, ZMIZ1.
- chr11:62,208,673–62,740,293, 39 genes, copy number 11: SCGB2A1, AP003306.1, SCGB1D2, SCGB2A2, SCGB1D4, NPM1P35, AP003306.2, ASRGL1, RCC2P6, AP003064.1, SCGB1A1, AP003064.2, AHNAK, AP001363.1, AP001363.2, EEF1G, AP002990.1, MIR6747, TUT1, MTA2, EML3, AP001458.1, ROM1, B3GAT3, GANAB, INTS5, AP001458.2, C11orf98, LBHD1, CSKMT, SNORA57, UQCC3, UBXN1, LRRN4CL, BSCL2, HNRNPUL2-BSCL2, GNG3, HNRNPUL2, TTC9C.
- chr11:69,147,228–71,997,597, 85 genes, copy number 18–28 (within-gene range 2–28) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 25. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
